Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3465, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3465-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Mass

Source of Specimen(s):
Kidney resection

Gross Description:
Received in one part.
Source of Tissue: 1. Labeled #1, "left kidney"

Gross Description: Received fresh labeled ", left kidney". It consists of a kidney with attached perinephric fat weighing a total of 262 grams and measuring 16.5 x 9.5 x 6 cm in greatest dimension. The ureteral stump measures 1.5 cm in length and 0.3 cm in diameter. The specimen is bisected to show a 10.5 x 5 x 5.5 cm kidney. An ill-defined fleshy brown tumor mid pole mass is identified measuring 5.5 x 5.5 x 4 cm in greatest dimension. Grossly the mass abuts the capsule and comes within 1 cm of the surrounding fat margin. It also obliterates approximately 50% of the inferior pole. The adrenal gland is absent. Representative sections submitted in 1A-1H.

Designation of Sections: 1A- urethral and vascular margins, 1B-1E- random section of tumor with closest capsule, 1F-1G- surrounding fat margin closest to tumor, 1H- tumor with adjacent uninvolved pelvis

Final Diagnosis:

1. Left kidney nephrectomy:
- Oncocytic chromophobe renal cell carcinoma, 5.5 cm.
- The tumor focally invades the renal capsule.
- No lymphovascular invasion is identified.
- Vascular and ureteral margins are uninvolved.

pTNM: pT1b Nx Mx

Procedures/Addenda

Addendum Date Ordered

Addendum Diagnosis

Chromosome Analysis performed by

Indication: Left renal mass

RESULTS: 45

[page 2 of 2]
49,XX+12[cp2]/46,xx[19]

Abnormal karyotype, [REDACTED]

INTERPRETATION:

Two mitotic cells examined were characterized by an additional copy of chromosome 12. No abnormalities were evident in the remaining 19 cells.

Trisomy 12 has been seen both in solid tumor and lymphoproliferative malignancies.

Source: NCI Genomic Data Commons file 4e07a87b-3ec9-41e2-8c9f-020014a0744e (TCGA-AK-3465.C68F05E9-F8B6-44BA-B827-1943FA5DF19F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).